Gene-level copy-number profile of specimen HCM-BROD-0834-C43-85M from HCMI case HCM-BROD-0834-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.9 years (28,828 days).
Specimen HCM-BROD-0834-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 899a0c23-1e3b-4b5f-acdc-31be75374ada.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0834-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/d303edf1-64c8-4217-9444-1254b5ae02e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 6,211; copy number 2: 50,137; copy number 3: 1,342; copy number 4: 44; copy number 5: 1,169.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,169 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:166,275,462–166,906,451, 13 genes, copy number 5 (within-gene range 3–6): AL121956.5, PRR18, SFT2D1, HNRNPA1P49, MPC1, AL022069.1, AL022069.2, RPS6KA2, RPS6KA2-IT1, MIR1913, RAMACL, AL023775.2, AL023775.1.
- chr8:58,805,412–59,760,263, 10 genes, copy number 5: TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1.
- chr8:59,893,856–60,516,795, 6 genes, copy number 5: AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1.
- chr8:69,424,849–70,403,808, 21 genes, copy number 5: LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14.
- chr8:72,196,334–145,066,685, 1,117 genes, copy number 5 (broad region; genes not listed).
- chr9:6,413,151–6,507,054, 2 genes, copy number 5: UHRF2, AL133480.1.

Autosomal genes at a single copy (total copy number 1): 3,663. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
